Somatic mutation profile of tumor specimen TCGA-EB-A6QZ-01A (aliquot TCGA-EB-A6QZ-01A-12D-A32N-08) from TCGA case TCGA-EB-A6QZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.9 years (28,078 days).
Specimen TCGA-EB-A6QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebcc7b4e-f618-44c7-92a3-a4cae0aa6b37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A6QZ-10B (Blood Derived Normal), aliquot TCGA-EB-A6QZ-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/553315b7-e740-457e-a5c3-1e5101ff988c

The open-access MAF lists 334 somatic variants for this specimen: 217 protein-altering or splice-affecting, 108 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 108, Nonsense Mutation 9, RNA 5, Splice Site 4, Frame Shift Del 3, Splice Region 2, Intron 2, Nonstop Mutation 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GFAP | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267607509, CM083520, COSV99493073; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AAK1 | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101275858, COSV68643863; called by muse, mutect2, varscan2
- ACTA2 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 101/120 reads (84%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV99826875; called by muse, mutect2, varscan2
- ADAM12 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 52/61 reads (85%) | catalogued as COSV100900063; called by muse, mutect2, varscan2
- ADAM7 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51545602, COSV99443048; called by muse, mutect2, varscan2
- ADGRV1 | c.5864C>T p.S1955F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101315521; called by muse, mutect2, varscan2
- AHNAK | c.2563A>G p.K855E | Missense Mutation (SNP) | VAF 177/421 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99945707; called by muse, mutect2, varscan2
- AIM2 | c.396G>A p.K132= | Splice Region (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100931028; called by muse, mutect2, varscan2
- ALB | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs748640859, COSV55735636; called by muse, mutect2, varscan2
- ANKFN1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374118988; called by muse, mutect2, varscan2
- ANKRD17 | c.6629G>A p.R2210K | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.121); catalogued as COSV100428594, COSV58219869; called by muse, mutect2, varscan2
- ARL10 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 74/194 reads (38%) | catalogued as COSV100118969; called by muse, varscan2
- ATRX | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 187/222 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100970112; called by muse, mutect2, varscan2
- B3GALT1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 56/108 reads (52%) | catalogued as rs759629237, COSV59908708; called by muse, mutect2, varscan2
- B4GALNT4 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100327208; called by muse, mutect2, varscan2
- B4GALNT4 | c.2666G>A p.G889E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100327209; called by muse, mutect2, varscan2
- BCAM | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV54300884, COSV99538515; called by muse, mutect2, varscan2
- BCAN | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752000890, COSV100227881; called by muse, mutect2, varscan2
- BCL11B | c.1697G>A p.R566H (on ENST00000357195 / NM_001282237.2; = p.R495H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.087); catalogued as COSV61738676; called by muse, mutect2, varscan2
- BSND | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.443); catalogued as COSV100987607; called by muse, mutect2, varscan2
- BTN3A1 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99175633; called by muse, mutect2, varscan2
- CARF | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100247504; called by muse, mutect2, varscan2
- CATSPER1 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs12720434, COSV56409598; called by muse, mutect2, varscan2
- CD200R1 | c.223G>A p.E75K (on ENST00000471858 / NM_170780.3; = p.E98K on NM_138806.4) | Missense Mutation (SNP) | VAF 72/80 reads (90%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV55604064; called by muse, mutect2, varscan2
- CDH18 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs771865565, COSV99932336; called by muse, mutect2, varscan2
- CDH6 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV99418144; called by muse, mutect2, varscan2
- CFAP65 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs781313239, COSV100444641; called by muse, mutect2, varscan2
- CHRNA9 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 156/307 reads (51%) | catalogued as COSV100038828; called by muse, mutect2, varscan2
- CHRNE | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.844); catalogued as COSV99544572; called by muse, mutect2, varscan2
- CHST4 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.105); catalogued as rs774643793, COSV100632812; called by muse, mutect2, varscan2
- CHTF18 | c.2482C>G p.P828A | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99242280; called by muse, mutect2, varscan2
- CIB4 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99994603; called by muse, mutect2, varscan2
- CIC | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 162/395 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs750344282, COSV99359016; called by muse, mutect2, varscan2
- CLCA4 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55368292, COSV99760242; called by muse, mutect2, varscan2
- CNOT6 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV99993382; called by muse, mutect2, varscan2
- COL21A1 | c.2137G>T p.G713* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99777519; called by muse, mutect2
- COL21A1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55161262; called by muse, mutect2, varscan2
- CPEB4 | c.1978T>C p.Y660H | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99436725; called by muse, mutect2, varscan2
- CRACD | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV99948618; called by muse, mutect2, varscan2
- CSMD3 | c.3944T>C p.M1315T (on ENST00000297405 / NM_001363185.1; = p.M1211T on NM_052900.3) | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV99825603; called by muse, mutect2, varscan2
- CSRP2 | c.184T>A p.Y62N | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60702543; called by muse, mutect2, varscan2
- CUBN | c.6421C>T p.P2141S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100912082; called by muse, mutect2, varscan2
- DACH1 | c.2161G>A p.V721I (on ENST00000619232 / NM_001366712.1; = p.V467I on NM_004392.6) | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV57490036; called by muse, mutect2, varscan2
- DCST1 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV99792696; called by muse, mutect2, varscan2
- DCUN1D4 | c.373A>T p.M125L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV100584362; called by muse, mutect2, varscan2
- DGKE | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99400694; called by muse, mutect2, varscan2
- DNAH10 | c.11876G>A p.R3959Q (on ENST00000409039; = p.R3898Q on NM_207437.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs1051360754, COSV101292217, COSV68989681; called by muse, mutect2, varscan2
- DNAH2 | c.7712A>G p.N2571S | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs772875004, COSV101209027; called by muse, mutect2, varscan2
- DNAH7 | c.6175C>T p.P2059S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100413909; called by muse, mutect2
- DNAH9 | c.537A>C p.Q179H | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99304270; called by muse, mutect2
- DPPA5 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs1238480576, COSV64875723, COSV64875816; called by muse, mutect2, varscan2
- DSCAML1 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100354698; called by muse, mutect2, varscan2
- DSG3 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770846167, COSV57129891; called by muse, mutect2, varscan2
- DSG3 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57128265; called by muse, mutect2, varscan2
- EMILIN3 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 111/212 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV100182375; called by muse, mutect2, varscan2
- ENPP6 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV57067076, COSV99698513; called by muse, mutect2, varscan2
- EPHB6 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs759570133, COSV100844136; called by muse, mutect2, varscan2
- EPN1 | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50036384, COSV99321587; called by muse, mutect2, varscan2
- ESAM | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99631635; called by muse, mutect2, varscan2
- FAT4 | c.13682C>T p.P4561L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV100627305; called by muse, mutect2, varscan2
- FCGR1A | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.454); catalogued as rs782053090, COSV64985099, COSV64985997; called by muse, mutect2, varscan2
- FGF14 | c.416T>G p.F139C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101084815; called by muse, mutect2, varscan2
- FIBIN | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.206); catalogued as COSV59412957; called by muse, mutect2, varscan2
- FLNC | c.4821T>G p.S1607R | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as COSV100367648; called by muse, mutect2, varscan2
- FREM1 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1052473452, COSV66525032; called by muse, mutect2, varscan2
- FRY | c.2029A>G p.M677V | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV66565273; called by muse, mutect2, varscan2
- FSIP2 | c.19402G>A p.D6468N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.106); catalogued as COSV100554024, COSV58091906; called by muse, mutect2, varscan2
- FSTL5 | c.2067C>A p.F689L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV100052943; called by muse, mutect2, varscan2
- GAS2L2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs199921910; called by muse, mutect2, varscan2
- GCG | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100972727, COSV64961667, COSV99072052; called by muse, mutect2, varscan2
- GFPT2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99517309; called by muse, mutect2, varscan2
- GIMAP6 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100188092; called by muse, mutect2, varscan2
- GLRB | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.962); catalogued as COSV52415619; called by muse, mutect2, varscan2
- GPC3 | c.1166+2T>G p.X389_splice | Splice Site (SNP) | VAF 24/30 reads (80%) | catalogued as COSV100892716; called by muse, mutect2, varscan2
- GRIN2D | c.2534T>C p.M845T | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99474225; called by muse, mutect2, varscan2
- GUCA1C | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99225171; called by muse, mutect2, varscan2
- HAT1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV99907805; called by muse, mutect2, varscan2
- HOXD3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV50883839; called by muse, mutect2, varscan2
- HSH2D | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.302); catalogued as COSV99507098; called by muse, mutect2, varscan2
- HSPA4L | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141362649; called by muse, mutect2, varscan2
- ICA1L | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100841661; called by muse, mutect2, varscan2
- IDO2 | c.1024G>A p.E342K (on ENST00000389060; = p.E355K on NM_194294.2) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.254); catalogued as COSV100584552; called by muse, mutect2, varscan2
- IGSF5 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV101011976; called by muse, mutect2, varscan2
- IL1RL1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV99293648; called by muse, mutect2, varscan2
- ITIH1 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775843794, COSV99834954; called by muse, mutect2, varscan2
- JAK1 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 94/211 reads (45%) | catalogued as COSV100691086, COSV61088166; called by muse, mutect2, varscan2
- JCAD | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs747355619, COSV100948099; called by muse, mutect2, varscan2
- JPH4 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV100436571; called by muse, mutect2, varscan2
- KCNA6 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs149897413, COSV54973858; called by muse, mutect2, varscan2
- KCNB2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.226); catalogued as rs778910036, COSV73048799; called by muse, mutect2, varscan2
- KCNMB2 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV64200680; called by muse, mutect2, varscan2
- KCTD8 | c.1225A>T p.N409Y | Missense Mutation (SNP) | VAF 138/343 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV100759159; called by muse, mutect2, varscan2
- KHNYN | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52160130, COSV52163540; called by muse, mutect2, varscan2
- KIF21B | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs772235540, COSV100143722; called by muse, mutect2, varscan2
- KMT2A | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 68/150 reads (45%) | catalogued as rs868934108, COSV63281620; called by muse, mutect2, varscan2
- KRTAP5-10 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 261/302 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as COSV64795824; called by muse, mutect2, varscan2
- LEXM | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.628); catalogued as rs753793925, COSV100827475; called by muse, mutect2, varscan2
- LGI2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101180759, COSV66122677; called by muse, mutect2, varscan2
- LMNTD2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs185418838, COSV54238120; called by muse, mutect2, varscan2
- LONP1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as rs770702880, COSV100638525; called by muse, mutect2, varscan2
- LRP1B | c.6709G>A p.G2237S | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV101252987, COSV67221996, COSV67259874; called by muse, mutect2, varscan2
- LRP1B | c.4411C>T p.H1471Y | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101252988; called by muse, mutect2, varscan2
- LRP2 | c.11137G>A p.G3713S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); catalogued as COSV99786662; called by muse, mutect2, varscan2
- LRRC42 | c.14T>A p.L5H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100066294; called by muse, mutect2, varscan2
- LRRC7 | c.1525G>A p.E509K (on ENST00000651989 / NM_001370785.2; = p.E476K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1318855534, COSV50409067; called by muse, mutect2, varscan2
- LRTM2 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.074); catalogued as COSV99765075; called by muse, mutect2, varscan2
- LTBR | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV99965183; called by muse, mutect2, varscan2
- MACC1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100255423, COSV100255774; called by muse, mutect2, varscan2
- MAGEA10 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 101/123 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99726581; called by muse, mutect2, varscan2
- MAN2A1 | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.107); catalogued as COSV99810492; called by muse, mutect2, varscan2
- MCC | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1287102776, COSV56730625; called by muse, mutect2, varscan2
- MGAM | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV71885324; called by muse, mutect2, varscan2
- MKI67 | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 241/289 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV100896192; called by muse, mutect2, varscan2
- MROH2B | c.1249A>G p.N417D | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV101270498; called by muse, mutect2, varscan2
- MTTP | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55505294; called by muse, mutect2, varscan2
- MUC2 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs745393847; called by muse, mutect2, varscan2
- MYH1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs753734214, COSV56845988; called by muse, mutect2, varscan2
- MYH2 | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99819308; called by muse, varscan2
- MYH4 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs267604704, COSV55124239; called by muse, mutect2, varscan2
- MYH6 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 109/124 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV62450029; called by muse, mutect2, varscan2
- MYH8 | c.4952G>A p.G1651E | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as rs375724202; called by muse, varscan2
- NDUFAF5 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100962031; called by muse, mutect2, varscan2
- NEGR1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100161055; called by muse, mutect2, varscan2
- NLRP4 | c.2633A>C p.D878A | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100015646; called by muse, mutect2, varscan2
- NOL6 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV53043294, COSV99954469; called by muse, mutect2, varscan2
- NPC1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 100/193 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs141243713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NWD1 | c.3917C>T p.S1306F | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100341782; called by muse, mutect2, varscan2
- OGFOD3 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256874637, COSV100234318, COSV57339370; called by muse, mutect2, varscan2
- OR5T3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs760208331, COSV100282683, COSV57382262; called by muse, mutect2, varscan2
- OR6C3 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV101110316; called by muse, mutect2, varscan2
- OR8D2 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 117/232 reads (50%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as COSV100658895; called by muse, mutect2, varscan2
- PARM1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100267786; called by muse, mutect2, varscan2
- PCDHGA7 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV99531312; called by muse, mutect2, varscan2
- PCLO | c.12281T>A p.F4094Y | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as COSV100427680; called by muse, mutect2, varscan2
- PCLO | c.8156G>A p.G2719E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs773627604, COSV61632500; called by muse, mutect2, varscan2
- PDE1B | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 121/238 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs749477163, COSV99226270; called by muse, mutect2, varscan2
- PDLIM2 | c.487G>A p.G163S (on ENST00000397760; = p.G413S on NM_021630.6) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99747239; called by muse, mutect2, varscan2
- PHKG1 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV99818025; called by muse, mutect2, varscan2
- PHLPP1 | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1272997868, COSV99407399; called by muse, mutect2, varscan2
- PITPNM1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 112/128 reads (88%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs140119237; called by muse, mutect2, varscan2
- PITPNM2 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV99758357; called by muse, mutect2, varscan2
- PLCZ1 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs899962141, COSV99855887; called by muse, mutect2, varscan2
- PLXNB1 | c.4456C>T p.P1486S | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602282; called by muse, mutect2, varscan2
- POU6F2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as rs1329241994, COSV68874483; called by muse, mutect2, varscan2
- PPP1R13B | c.2261C>T p.T754I | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99157608; called by muse, mutect2, varscan2
- PRB2 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 327/1124 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66982191; called by muse, varscan2
- PSG4 | c.786T>G p.C262W | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99736334; called by muse, mutect2, varscan2
- PTBP3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 68/86 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV99270116; called by muse, mutect2, varscan2
- PTBP3 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 68/87 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99270120; called by muse, mutect2, varscan2
- RABGAP1L | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as COSV99267984; called by muse, mutect2, varscan2
- RASA2 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.676); catalogued as COSV99655641; called by muse, mutect2, varscan2
- RASSF9 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV63435273; called by muse, mutect2
- RBM42 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99386876; called by muse, mutect2, varscan2
- RPE65 | c.598T>A p.F200I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as COSV99253615; called by muse, mutect2, varscan2
- SCP2 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101026842; called by muse, mutect2, varscan2
- SEMA3E | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57084466, COSV57094729; called by muse, mutect2, varscan2
- SEMA4C | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); catalogued as rs763831570, COSV100560742; called by muse, mutect2, varscan2
- SEPHS2 | c.178T>A p.Sec60R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.52); catalogued as COSV101529303; called by muse, mutect2, varscan2
- SETD3 | c.197-1G>A p.X66_splice | Splice Site (SNP) | VAF 59/119 reads (50%) | catalogued as COSV100074851; called by muse, mutect2, varscan2
- SETD3 | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs982595962, COSV100074852; called by muse, mutect2, varscan2
- SLC10A4 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906776; called by muse, mutect2, varscan2
- SLC9A4 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 60/114 reads (53%) | catalogued as rs754266683, COSV54829700; called by muse, mutect2, varscan2
- SLCO1B3 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs369045586, COSV53933377; called by muse, mutect2, varscan2
- SMTN | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100293994; called by muse, mutect2, varscan2
- SNAP25 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99654537; called by muse, mutect2, varscan2
- SPATA16 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 86/103 reads (83%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100650917; called by muse, mutect2, varscan2
- SPATA45 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100260274; called by muse, mutect2, varscan2
- ST8SIA4 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 37/100 reads (37%) | PolyPhen probably damaging (0.962); catalogued as rs866022278, COSV51515947, COSV99185125; called by muse, mutect2, varscan2
- SYNE1 | c.6977C>T p.S2326L (on ENST00000367255 / NM_182961.4; = p.S2333L on NM_033071.3) | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.755); catalogued as rs752405422, COSV54921578; called by muse, mutect2, varscan2
- TARDBP | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1207245151, COSV53570807, COSV99534383; called by muse, mutect2, varscan2
- TCN1 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953100; called by muse, mutect2, varscan2
- THAP4 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV101125996; called by muse, mutect2, varscan2
- TIAM1 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.914); catalogued as COSV99732977; called by muse, mutect2, varscan2
- TM7SF2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 180/421 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54208982, COSV99659548; called by muse, mutect2, varscan2
- TMEM154 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV58589997, COSV58591294; called by muse, mutect2, varscan2
- TMEM161B | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99680240; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100835810; called by muse, mutect2, varscan2
- TOP2A | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV101396050; called by muse, mutect2, varscan2
- TOP3B | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100592340; called by muse, mutect2, varscan2
- TOX2 | c.235C>T p.P79S (on ENST00000358131 / NM_001098798.2; = p.P28S on NM_032883.3) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169843883, COSV57883524; called by muse, mutect2, varscan2
- TSSK1B | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as COSV101180957; called by muse, mutect2, varscan2
- TTBK1 | c.3196G>A p.G1066S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99443792; called by muse, mutect2, varscan2
- TTC37 | c.3793C>T p.L1265F | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV100706387; called by muse, mutect2, varscan2
- TTN | c.13172C>T p.P4391L (on ENST00000591111; = p.P4345L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | PolyPhen benign (0.109); catalogued as rs778412304, COSV100595561; called by muse, mutect2, varscan2
- USP7 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100783989; called by muse, mutect2, varscan2
- VRTN | c.368T>G p.M123R | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99832126; called by muse, mutect2, varscan2
- VSTM1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100618671; called by muse, mutect2, varscan2
- WBP11 | c.1769A>G p.K590R | Missense Mutation (SNP) | VAF 135/333 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV99660553; called by muse, mutect2, varscan2
- WDFY3 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99882139; called by muse, mutect2, varscan2
- WDR72 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100854227; called by muse, mutect2, varscan2
- WNT3 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99843072; called by muse, mutect2, varscan2
- WWC3 | c.2017A>T p.R673* | Nonsense Mutation (SNP) | VAF 149/190 reads (78%) | catalogued as COSV101081070; called by muse, mutect2, varscan2
- YIPF2 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99449824; called by muse, mutect2, varscan2
- ZDHHC8 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1158903659, COSV100272623; called by muse, mutect2, varscan2
- ZEB2 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100355054; called by muse, varscan2
- ZFHX4 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866644618, COSV50484402; called by muse, mutect2, varscan2
- ZFPM1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1330912722, COSV100128199; called by muse, mutect2, varscan2
- ZFPM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV68274293; called by muse, mutect2, varscan2
- ZNF182 | c.-25C>T | Splice Region (SNP) | VAF 20/25 reads (80%) | catalogued as COSV100429236; called by muse, mutect2, varscan2
- ZNF205 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV99530179; called by muse, mutect2, varscan2
- ZNF229 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV52159752, COSV99350065; called by muse, mutect2, varscan2
- ZNF229 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99350066; called by muse, mutect2, varscan2
- ZNF276 | c.841G>A p.D281N (on ENST00000443381 / NM_001113525.2; = p.D206N on NM_152287.4) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99234580; called by muse, mutect2, varscan2
- ZNF404 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV100182310; called by muse, mutect2, varscan2
- ZNF470 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57968345; called by muse, mutect2, varscan2
- ZNF592 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV55440263; called by muse, mutect2, varscan2
- ZSWIM2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as COSV54574967; called by muse, mutect2, varscan2
- ACAT1 | c.494_504del p.R165Tfs*8 | Frame Shift Del (DEL) | VAF 65/172 reads (38%) | called by mutect2, pindel, varscan2
- C2orf76 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- C2orf76 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM50B | c.727_734del p.I243Afs*28 | Frame Shift Del (DEL) | VAF 55/111 reads (50%) | called by mutect2, pindel, varscan2
- HNF1B | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MTUS2 | c.1161_1162del p.E388Afs*19 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRDV1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- VRK2 | c.1510_*10del | Nonstop Mutation (DEL) | VAF 27/98 reads (28%) | called by mutect2, pindel
- ADAMDEC1 | c.1272G>A p.G424= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV56475167; called by muse, mutect2, varscan2
- ADGRG2 | c.1971G>A p.R657= (on ENST00000379869 / NM_001079858.3; = p.R654= on NM_005756.4) | Silent (SNP) | VAF 47/61 reads (77%) | catalogued as COSV100491903; called by muse, mutect2, varscan2
- ADGRV1 | c.6255G>A p.A2085= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs768812855, COSV67985417; called by muse, mutect2, varscan2
- APOB | c.7167C>T p.Y2389= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as CD931404, COSV99263770; called by muse, mutect2, varscan2
- APOL4 | c.681C>A p.P227= (on ENST00000352371 / NM_145660.2; = p.P224= on NM_030643.4) | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV100274056; called by muse, mutect2, varscan2
- ASXL3 | c.5010T>C p.S1670= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99323532; called by muse, mutect2
- ATN1 | c.162C>T p.A54= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs782631089, COSV100755683; called by muse, mutect2, varscan2
- ATP6V0D2 | c.468C>T p.I156= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as rs1208196259, COSV53414875, COSV53416315; called by muse, mutect2, varscan2
- ATP8B1 | c.1509G>A p.G503= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99376859; called by muse, mutect2, varscan2
- ATP8B4 | c.2868C>T p.F956= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs150358448, COSV52721696; called by muse, mutect2, varscan2
- ATR | c.7672C>T p.L2558= | Silent (SNP) | VAF 55/62 reads (89%) | catalogued as COSV100637685; called by muse, mutect2, varscan2
- B4GALNT4 | c.477C>T p.S159= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as rs749425037, COSV57326482; called by muse, mutect2, varscan2
- BICDL1 | c.738C>T p.I246= | Silent (SNP) | VAF 43/62 reads (69%) | catalogued as rs759711631, COSV101287159; called by muse, mutect2, varscan2
- BNIP5 | c.975G>A p.K325= | Silent (SNP) | VAF 78/197 reads (40%) | catalogued as rs1440766722, COSV101465115; called by muse, mutect2, varscan2
- BTNL8 | c.1146G>T p.L382= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as COSV99180428; called by muse, mutect2, varscan2
- CACNA1A | c.1830C>T p.S610= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV100801052; called by muse, mutect2, varscan2
- CACNA1G | c.2253C>T p.I751= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs542091261, COSV100661207; called by muse, mutect2, varscan2
- CASZ1 | c.2499C>T p.T833= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs1050323301, COSV100680786; called by muse, mutect2, varscan2
- CATIP | c.123G>A p.K41= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV56824971; called by muse, mutect2, varscan2
- CD163 | c.1821C>T p.L607= | Silent (SNP) | VAF 85/154 reads (55%) | catalogued as COSV100775690; called by muse, mutect2, varscan2
- CD163L1 | c.3654C>T p.S1218= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as COSV100549716; called by muse, mutect2, varscan2
- CDIN1 | c.378G>A p.R126= (on ENST00000437989; = p.R28= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100589632; called by muse, mutect2, varscan2
- CHD6 | c.1959C>T p.T653= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as rs143570961, COSV100497796; called by muse, mutect2, varscan2
- CLUL1 | c.234G>A p.K78= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV58111195, COSV99075617; called by muse, mutect2, varscan2
- CNTN5 | c.2220C>A p.P740= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV99673210; called by muse, mutect2, varscan2
- COL27A1 | c.510G>A p.L170= | Silent (SNP) | VAF 56/62 reads (90%) | catalogued as COSV100620744; called by muse, mutect2, varscan2
- COL5A3 | c.3123C>T p.S1041= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1413555188, COSV53411013; called by muse, mutect2, varscan2
- CRYBB1 | c.306C>T p.V102= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs781712006, COSV53233308; called by muse, mutect2, varscan2
- CTSC | c.207G>A p.Q69= | Silent (SNP) | VAF 70/80 reads (88%) | catalogued as COSV99910503; called by muse, mutect2, varscan2
- CYP4A22 | c.246C>T p.F82= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV99594604; called by muse, varscan2
- CYP4B1 | c.234G>A p.P78= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs202229746, COSV99596819; called by muse, mutect2, varscan2
- DENND1A | c.2241C>T p.A747= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV101011803; called by muse, mutect2, varscan2
- DLGAP3 | c.267C>T p.F89= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV52395974; called by muse, mutect2
- DNAH3 | c.12093G>A p.T4031= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs373242503; called by muse, mutect2, varscan2
- DSCAM | c.153C>T p.I51= | Silent (SNP) | VAF 65/176 reads (37%) | catalogued as COSV68654048; called by muse, mutect2, varscan2
- DYRK4 | c.249G>A p.T83= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1349776146, COSV50545366; called by muse, mutect2, varscan2
- E2F8 | c.90C>T p.I30= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs758938603, COSV100001315; called by muse, mutect2, varscan2
- EPHX2 | c.1209G>A p.R403= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV100994477; called by muse, mutect2, varscan2
- FBLN2 | c.906G>A p.R302= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as COSV99851439; called by muse, mutect2, varscan2
- FER1L5 | c.4422G>A p.V1474= (on ENST00000623019; = p.V1447= on NM_001293083.2) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV101208807; called by muse, mutect2, varscan2
- GABRA3 | c.807C>T p.F269= | Silent (SNP) | VAF 47/60 reads (78%) | catalogued as COSV64796380, COSV64804564; called by muse, mutect2, varscan2
- GIGYF2 | c.3792G>A p.K1264= | Silent (SNP) | VAF 46/84 reads (55%) | catalogued as COSV101003914; called by muse, varscan2
- IL22RA1 | c.1269A>G p.K423= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV99582796; called by muse, mutect2, varscan2
- IRX6 | c.447C>T p.R149= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99306205; called by muse, mutect2, varscan2
- JPH4 | c.1302C>T p.S434= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as rs182379018; called by muse, mutect2, varscan2
- KCNA6 | c.534C>T p.I178= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV99768348; called by muse, mutect2, varscan2
- KCND2 | c.600C>T p.I200= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV58594286; called by muse, mutect2, varscan2
- KLHL40 | c.1788C>T p.V596= | Silent (SNP) | VAF 73/88 reads (83%) | catalogued as COSV99825339; called by muse, mutect2, varscan2
- KRTAP24-1 | c.120C>T p.S40= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100447312; called by muse, mutect2, varscan2
- LRFN1 | c.747C>T p.F249= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs755225764, COSV99952645; called by muse, mutect2, varscan2
- LRRC1 | c.564T>C p.N188= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV100906227; called by muse, mutect2, varscan2
- LTBR | c.861C>T p.F287= | Silent (SNP) | VAF 80/222 reads (36%) | catalogued as rs780363968, COSV57438247; called by muse, mutect2, varscan2
- MARCO | c.642G>A p.G214= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV100503224; called by muse, mutect2, varscan2
- MEGF10 | c.1653C>T p.H551= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs760467865, COSV99174721; called by muse, mutect2, varscan2
- MEGF11 | c.183C>T p.F61= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99986902; called by muse, mutect2, varscan2
- MID2 | c.2199C>T p.T733= | Silent (SNP) | VAF 33/46 reads (72%) | catalogued as rs1392959126, COSV99464064, COSV99464898; called by muse, mutect2, varscan2
- MMP28 | c.771C>A p.L257= | Silent (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- MORC1 | c.51C>T p.F17= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs1324985399, COSV51714699; called by muse, mutect2, varscan2
- MPI | c.1071T>C p.T357= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100086225; called by muse, mutect2, varscan2
- MXRA5 | c.3852G>A p.L1284= | Silent (SNP) | VAF 81/101 reads (80%) | catalogued as COSV99475887; called by muse, mutect2, varscan2
- MYH3 | c.2919G>A p.E973= | Silent (SNP) | VAF 113/298 reads (38%) | catalogued as COSV99877754; called by muse, mutect2, varscan2
- NPAS3 | c.2007C>T p.P669= (on ENST00000356141 / NM_001164749.2; = p.P637= on NM_022123.3) | Silent (SNP) | VAF 56/66 reads (85%) | catalogued as COSV100639680; called by muse, mutect2, varscan2
- NREP | c.96C>T p.V32= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV99972645; called by muse, mutect2, varscan2
- NRK | c.894C>T p.F298= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs1367358193, COSV54603178; called by muse, mutect2, varscan2
- OLFM3 | c.666G>A p.L222= (on ENST00000338858 / NM_001288821.1; = p.L202= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV100128925; called by muse, mutect2, varscan2
- OR13C5 | c.153G>A p.L51= | Silent (SNP) | VAF 48/81 reads (59%) | catalogued as COSV101053017; called by muse, mutect2, varscan2
- OR2T33 | c.885G>A p.V295= | Silent (SNP) | VAF 114/270 reads (42%) | catalogued as rs573271304, COSV100531623, COSV58813909; called by muse, mutect2, varscan2
- OR7G2 | c.156C>T p.F52= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV59688603; called by muse, mutect2, varscan2
- PCDH1 | c.2979G>A p.V993= | Silent (SNP) | VAF 31/34 reads (91%) | catalogued as rs1312261609, COSV54612987; called by muse, mutect2, varscan2
- PCDHB15 | c.480G>A p.L160= | Silent (SNP) | VAF 66/118 reads (56%) | catalogued as COSV99178822; called by muse, mutect2, varscan2
- PCDHGB7 | c.1473C>T p.L491= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs1356380695, COSV99531314; called by muse, mutect2, varscan2
- PCLO | c.12282C>T p.F4094= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs757947018, COSV61665886; called by muse, mutect2, varscan2
- PCLO | c.1128T>A p.T376= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100427681; called by muse, mutect2
- PCSK9 | c.1833G>A p.K611= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1450967500, COSV99598914; called by muse, mutect2, varscan2
- PLCH2 | c.3342C>T p.P1114= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99615576; called by muse, mutect2
- PSG7 | c.660G>A p.R220= | Silent (SNP) | VAF 296/601 reads (49%) | catalogued as rs1386661282, COSV101343204; called by muse, mutect2, varscan2
- PTPRB | c.273C>T p.P91= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as rs754380393, COSV99316358; called by muse, mutect2, varscan2
- RABGAP1L | c.804C>T p.T268= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV99267980; called by muse, mutect2, varscan2
- RANBP2 | c.3516T>C p.F1172= | Silent (SNP) | VAF 94/186 reads (51%) | catalogued as COSV99311306; called by muse, mutect2, varscan2
- RBM42 | c.573C>T p.A191= | Silent (SNP) | VAF 111/257 reads (43%) | catalogued as rs149753042; called by muse, mutect2, varscan2
- SAPCD1 | c.108C>T p.F36= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1433989942, COSV100991747; called by muse, mutect2, varscan2
- SCUBE1 | c.2115G>A p.V705= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100682894; called by muse, mutect2, varscan2
- SIGLEC12 | c.666C>T p.L222= (on ENST00000291707 / NM_053003.4; = p.L104= on NM_033329.2) | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as rs1207388462, COSV52466323; called by muse, mutect2, varscan2
- SLC2A14 | c.1185G>A p.L395= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100533550; called by muse, mutect2, varscan2
- SLC30A3 | c.129G>A p.E43= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs865934137, COSV99273462; called by muse, mutect2, varscan2
- SLITRK5 | c.1005C>T p.R335= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as COSV100280338; called by muse, mutect2, varscan2
- SMARCA2 | c.4392A>T p.L1464= | Silent (SNP) | VAF 86/104 reads (83%) | catalogued as COSV100190136; called by muse, mutect2, varscan2
- SNRNP200 | c.5463C>T p.Y1821= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV100107135; called by muse, mutect2, varscan2
- ST8SIA4 | c.225C>T p.S75= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV99185124; called by muse, mutect2, varscan2
- SYT2 | c.1122C>T p.I374= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV100937120; called by muse, mutect2, varscan2
- TEKT2 | c.1047C>T p.I349= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52881574; called by muse, mutect2, varscan2
- THEG | c.663G>C p.R221= | Silent (SNP) | VAF 98/277 reads (35%) | catalogued as COSV100700576; called by muse, mutect2, varscan2
- TMCO1 | c.423C>T p.S141= (on ENST00000612311 / NM_001256164.1; = p.S90= on NM_019026.6) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs775406963, COSV100903103; called by muse, mutect2, varscan2
- TRIM56 | c.1500G>A p.R500= | Silent (SNP) | VAF 103/260 reads (40%) | catalogued as COSV100046987; called by muse, mutect2, varscan2
- TRPC4AP | c.1755C>T p.L585= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as rs1416020271, COSV99327825; called by muse, mutect2, varscan2
- TTN | c.13173C>T p.P4391= (on ENST00000591111; = p.P4345= on NM_003319.4) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100595559; called by muse, mutect2, varscan2
- UBQLN3 | c.1045T>C p.L349= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV100293368; called by muse, mutect2, varscan2
- VENTX | c.252G>A p.K84= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV100383997; called by muse, mutect2, varscan2
- VRK3 | c.936C>T p.I312= | Silent (SNP) | VAF 90/263 reads (34%) | catalogued as COSV100371323; called by muse, mutect2, varscan2
- VSTM1 | c.414C>T p.V138= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs377301917; called by muse, mutect2, varscan2
- VWF | c.352C>T p.L118= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as COSV99778077; called by muse, mutect2, varscan2
- YIPF2 | c.66C>T p.T22= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV99449821; called by muse, mutect2, varscan2
- ZEB2 | c.3255G>A p.A1085= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as rs1266781321, COSV100355055; called by muse, varscan2
- ZFHX4 | c.180C>T p.A60= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as COSV99256818; called by muse, mutect2, varscan2
- ZNF491 | c.336C>T p.F112= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV60056887; called by muse, mutect2, varscan2
- ZNF678 | c.1014C>T p.S338= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100652623; called by muse, mutect2, varscan2
- ZNF878 | c.867G>A p.R289= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs779047914, COSV101521178; called by muse, mutect2, varscan2
- ZRANB3 | c.342G>A p.Q114= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV51502495, COSV99922690; called by muse, mutect2, varscan2
- BIRC8 | n.1411G>A | RNA (SNP) | VAF 79/213 reads (37%) | catalogued as rs761492573, COSV70346634; called by muse, mutect2, varscan2
- DLX3 | c.-1G>A | 5'UTR (SNP) | VAF 27/48 reads (56%) | catalogued as COSV101460518; called by muse, mutect2, varscan2
- GK5 | c.816+145C>T | Intron (SNP) | VAF 15/18 reads (83%) | catalogued as COSV101242093; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049853 A>G | 3'Flank (SNP) | VAF 28/52 reads (54%) | catalogued as COSV51541194; called by muse, mutect2, varscan2
- MIR516B2 | n.70G>A | RNA (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- MIR526B | n.23G>A | RNA (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- PYY3 | n.79G>A | RNA (SNP) | VAF 20/25 reads (80%) | catalogued as rs782438507; called by muse, mutect2, varscan2
- SFTA3 | n.924C>T | RNA (SNP) | VAF 89/117 reads (76%) | catalogued as rs267603984, COSV69488913; called by muse, mutect2, varscan2
- SV2C | c.581-21009C>T | Intron (SNP) | VAF 176/462 reads (38%) | catalogued as rs756780447, COSV59220170; called by muse, mutect2, varscan2
